Gene-level copy-number profile of tumor specimen TCGA-ER-A19J-06A from TCGA case TCGA-ER-A19J, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 54.2 years (19,801 days).
Specimen TCGA-ER-A19J-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.5b2f6214-fd69-4c6b-87b6-d08e72ee9b51.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-ER-A19J-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/bdd450ad-406e-49c6-a7b6-a734bd7f0521

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 6,410; copy number 2: 44,461; copy number 3: 2,765; copy number 4: 4,426; copy number 5: 223; copy number 7: 214; copy number 8: 1,320.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-ER-A19J-06A-11D-A194-01): tumor purity 0.91, ploidy 2.28, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:5,142,411–5,142,707, 1 gene: RN7SL318P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,757 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:78,017,055–79,453,667, 1 gene, copy number 5 (within-gene range 4–5): MAGI2.
- chr7:78,392,626–97,201,483, 222 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr8:46,028,804–145,066,685, 1,534 genes, copy number 7–8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 4,029. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
